Gene-level copy-number profile of tumor specimen TCGA-56-A4BW-01A from TCGA case TCGA-56-A4BW, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 55.6 years (20,301 days).
Specimen TCGA-56-A4BW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.e9b95ff7-b359-495e-b8b5-8e451ea566cc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-56-A4BW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d072494b-1e52-482b-a1e4-346336cbe8b7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 15,266; copy number 2: 31,561; copy number 3: 9,879; copy number 4: 1,911; copy number 5: 825; copy number 6: 75; copy number 7: 160; copy number 10: 26; copy number 11: 2; copy number 12: 21; copy number 14: 18; copy number 15: 15; copy number 17: 9; copy number 19: 31.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-56-A4BW-01A-11D-A24C-01): tumor purity 0.58, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,019,329–2,030,758, 1 gene: GABRD.
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–1): MTAP, AL359922.1.
- chr9:21,858,910–22,128,103, 10 genes (within-gene range 0–1): AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,169 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,049,203–6,101,193, 88 genes, copy number 6–17 (within-gene range 2–17) (broad region; genes not listed).
- chr3:93,843,764–97,752,460, 28 genes, copy number 10–15 (within-gene range 2–15): RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1, AC140059.1, WDR82P1, LINC00879, RPS18P6, MTHFD2P1, AC106719.1, AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1, AC109782.1, EPHA6.
- chr3:143,855,739–155,745,071, 184 genes, copy number 5 (broad region; genes not listed).
- chr3:164,001,606–192,917,856, 462 genes, copy number 5 (broad region; genes not listed).
- chr7:84,847,877–85,489,293, 9 genes, copy number 7: AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972.
- chr7:87,503,017–87,713,323, 1 gene, copy number 12 (within-gene range 3–12): ABCB1.
- chr7:87,627,548–101,629,296, 325 genes, copy number 5–19 (broad region; genes not listed).
- chr20:8,929,895–13,996,443, 66 genes, copy number 5 (broad region; genes not listed).
- chr20:14,003,508–14,523,314, 6 genes, copy number 5: RPS3P1, AIMP1P1, RN7SL864P, FLRT3, RNU6-228P, AL121582.1.

Autosomal genes at a single copy (total copy number 1): 13,155. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
